Somatic mutation profile of tumor specimen ALCH-ABYV-TTP1-A (aliquot ALCH-ABYV-TTP1-A-1-0-D-A491-36) from ALCHEMIST case ALCH-ABYV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.3 years (21,665 days).
Specimen ALCH-ABYV-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22caf402-ed09-491e-9314-390d2c0d3a30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABYV-NB1-A (Blood Derived Normal), aliquot ALCH-ABYV-NB1-A-1-0-D-A491-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7120747-7f49-42dc-b882-fbeac4bbbafa

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Intron 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DPP8 | c.1478G>A p.R493Q (on ENST00000341861 / NM_001320875.2; = p.R477Q on NM_017743.6) | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs752452586, COSV55675861; called by muse, mutect2, varscan2
- HNRNPU | c.582C>G p.F194L | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs764150176; called by muse, mutect2, varscan2
- IPO8 | c.2284G>A p.V762I | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs774490198, COSV56239806; called by muse, mutect2
- LRFN1 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs370463385; called by muse, mutect2, varscan2
- NRAP | c.3674C>T p.A1225V (on ENST00000359988 / NM_001322945.2; = p.A1190V on NM_006175.4) | Missense Mutation (SNP) | VAF 50/297 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs200747403; called by muse, mutect2, varscan2
- WDR45 | c.821G>A p.R274H (on ENST00000376372 / NM_001029896.2; = p.R275H on NM_007075.3) | Missense Mutation (SNP) | VAF 25/580 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs782754327; called by muse, mutect2
- C5 | c.4549C>G p.Q1517E | Missense Mutation (SNP) | VAF 114/733 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COPS9 | c.157G>A p.D53N (on ENST00000607357 / NM_001163424.2; = p.D84N on NM_138336.1) | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.017); called by muse, mutect2
- DNAH7 | c.10844T>C p.V3615A | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- EVI2A | c.584C>A p.T195N | Missense Mutation (SNP) | VAF 62/349 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MIB2 | c.56C>A p.T19K | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2
- RPL11 | c.7-3C>T | Splice Region (SNP) | VAF 61/351 reads (17%) | called by muse, mutect2, varscan2
- SCARF1 | c.1456C>G p.L486V | Missense Mutation (SNP) | VAF 75/412 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TMPRSS11A | c.512A>C p.E171A | Missense Mutation (SNP) | VAF 51/322 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- WDR87 | c.2765C>T p.T922I | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF619 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DOCK5 | c.5130G>C p.S1710= | Silent (SNP) | VAF 60/275 reads (22%) | catalogued as rs201702382, COSV52414115; called by muse, mutect2, varscan2
- IGKV6D-21 | c.6G>A p.S2= | Silent (SNP) | VAF 168/979 reads (17%) | catalogued as rs1225494144; called by muse, mutect2, varscan2
- LCN2 | c.582G>A p.Q194= | Silent (SNP) | VAF 181/537 reads (34%) | called by muse, varscan2
- UQCRFS1 | c.18C>T p.S6= | Silent (SNP) | VAF 37/153 reads (24%) | catalogued as COSV59185558; called by muse, mutect2, varscan2
- HEPACAM | c.427+36C>A | Intron (SNP) | VAF 22/606 reads (4%) | called by muse, mutect2
- MTHFD1L | c.2586+6349C>T | Intron (SNP) | VAF 12/240 reads (5%) | called by muse, mutect2
